Somatic mutation profile of tumor specimen MBCProject_2661_T1_WES (aliquot MBCProject_2661_T1_WES_1) from CMI case MBCProject_2661, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 34.1 years (12,444 days).
Specimen MBCProject_2661_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 22c97ba8-9b1d-428e-a8b3-8340fe97cb94.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_2661_SALIVA (Saliva), aliquot MBCProject_2661_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e920464d-6929-4e3d-9c05-624c2231b923

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 2, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APOA2 | c.64C>G p.R22G | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV57155622, COSV99248250; called by muse, varscan2
- ANKRD24 | c.3047C>G p.A1016G | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, varscan2
- ACE | c.2832G>A p.S944= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as rs866899407; called by muse, varscan2
- TEPSIN | c.1002G>A p.P334= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs553598437, COSV100329507; called by mutect2, varscan2
